Somatic mutation profile of tumor specimen TCGA-CN-6989-01A (aliquot TCGA-CN-6989-01A-11D-1912-08) from TCGA case TCGA-CN-6989, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.4 years (23,515 days).
Specimen TCGA-CN-6989-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dffee00a-8723-4677-939a-ed086653329d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6989-10A (Blood Derived Normal), aliquot TCGA-CN-6989-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6914166-6780-4c73-9979-b7a305ef70ad

The open-access MAF lists 110 somatic variants for this specimen: 76 protein-altering or splice-affecting, 29 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 29, Nonsense Mutation 7, RNA 3, Frame Shift Del 2, 5'UTR 1, 5'Flank 1, Nonstop Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99574367; called by muse, mutect2, varscan2
- ADAMTS5 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV99537274; called by muse, mutect2, varscan2
- ADAMTS8 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs755129801, COSV99960595; called by muse, mutect2, varscan2
- AKAP1 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100532745; called by muse, mutect2, varscan2
- ANGPTL6 | c.1343G>C p.W448S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99463445; called by muse, mutect2, varscan2
- CBLN4 | c.287A>C p.D96A | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99290430; called by muse, mutect2, varscan2
- CDH2 | c.2629A>C p.S877R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296229; called by muse, mutect2, varscan2
- CDYL2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs1161870624, COSV73653843; called by muse, mutect2, varscan2
- CFAP61 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99843950; called by muse, mutect2, varscan2
- CILP | c.1892A>G p.N631S | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99973030; called by muse, mutect2, varscan2
- CLIP1 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as rs1382895063, COSV100211418; called by muse, mutect2, varscan2
- CNTN6 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1414060641, COSV100610388; called by muse, mutect2, varscan2
- CREBRF | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as rs1397140996, COSV99755488; called by muse, mutect2, varscan2
- CSE1L | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.675); catalogued as COSV99521912; called by muse, mutect2, varscan2
- CSPG4 | c.2014C>T p.R672* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as rs368004567; called by muse, mutect2, varscan2
- CUL3 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023967; called by muse, mutect2, varscan2
- DPY19L3 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.137); catalogued as rs1198396072, COSV100639142; called by muse, mutect2, varscan2
- FAM20A | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as rs1397452498, COSV99873249; called by muse, mutect2, varscan2
- FAT1 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 124/304 reads (41%) | catalogued as rs369805914; called by muse, mutect2, varscan2
- FLAD1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99422230; called by muse, mutect2, varscan2
- FLG | c.5065G>C p.A1689P | Missense Mutation (SNP) | VAF 165/607 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100911232; called by muse, mutect2, varscan2
- FNBP4 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99771520; called by muse, mutect2, varscan2
- FRY | c.4862C>A p.A1621D | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100968937, COSV66566354, COSV66574218; called by muse, mutect2, varscan2
- GAREM1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99330373; called by muse, mutect2, varscan2
- GPR37 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV100390659; called by muse, mutect2, varscan2
- GRID2 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs374167901, COSV56193082; called by muse, mutect2, varscan2
- LARGE1 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100504923; called by muse, mutect2, varscan2
- LRRC37A2 | c.3836T>C p.I1279T | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs756624471, COSV100238675; called by muse, mutect2, varscan2
- LRRC37B | c.1559T>G p.I520R | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100496116; called by muse, mutect2, varscan2
- MAPK9 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100558213; called by muse, mutect2
- MED12L | c.4782G>T p.E1594D | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs762721689, COSV99852109; called by muse, mutect2, varscan2
- MEX3D | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101183477; called by muse, mutect2, varscan2
- MEX3D | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101183478; called by muse, mutect2, varscan2
- MRPS30 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99138132; called by muse, mutect2
- NEK2 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1356090201, COSV100878553; called by muse, mutect2
- NEURL2 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.123); catalogued as COSV99509738; called by muse, mutect2, varscan2
- NF1 | c.4344T>A p.S1448R (on ENST00000358273 / NM_001042492.3; = p.S1427R on NM_000267.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100646355; called by muse, mutect2, varscan2
- NOTCH1 | c.2217C>A p.C739* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV53090533, COSV99486359; called by muse, mutect2, varscan2
- NOTCH2 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99863271; called by muse, mutect2, varscan2
- ODAM | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV101258041, COSV68573311; called by muse, mutect2, varscan2
- OR2Z1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs199861220; called by muse, mutect2, varscan2
- OR5T1 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.491); catalogued as COSV100478834; called by muse, mutect2, varscan2
- PELP1 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99342656; called by muse, mutect2, varscan2
- PEX11A | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs750192613, COSV100261464; called by muse, mutect2, varscan2
- PLXNB2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs754158572, COSV100833924; called by muse, mutect2, varscan2
- PRRC2C | c.7406A>G p.Y2469C (on ENST00000367742; = p.Y2467C on NM_015172.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144912; called by muse, mutect2, varscan2
- REC114 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100461201; called by muse, mutect2, varscan2
- RFC5 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs779555138, COSV99969793; called by muse, mutect2, varscan2
- RPS23 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV99688419; called by muse, mutect2, varscan2
- SEMA5A | c.2618del p.P873Rfs*86 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs1561106423; called by mutect2, pindel, varscan2
- SHANK2 | c.5146G>C p.E1716Q | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV53585925, COSV99571432; called by muse, mutect2
- SHANK2 | c.3681G>T p.M1227I | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99572901; called by muse, mutect2
- SLC4A8 | c.2700+1G>A p.X900_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100176565; called by muse, mutect2, varscan2
- SMCHD1 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99861064; called by muse, mutect2, varscan2
- SMUG1 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV99679377; called by muse, mutect2, varscan2
- SORBS3 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV53554022; called by muse, mutect2, varscan2
- SPTLC1 | c.1420T>C p.*474Qext*27 | Nonstop Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99364641; called by muse, varscan2
- SRRT | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99573878; called by muse, mutect2, varscan2
- STEAP4 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57328022; called by muse, mutect2
- TBX22 | c.1005G>T p.L335F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as COSV100960693; called by muse, mutect2, varscan2
- TCERG1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99694577; called by muse, mutect2, varscan2
- TP53 | c.764dup p.T256Hfs*8 | Frame Shift Ins (INS) | VAF 32/98 reads (33%) | catalogued as COSV99037193; called by mutect2, pindel, varscan2
- TRIM24 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV58979285; called by muse, mutect2
- TRIM24 | c.1288A>T p.S430C | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV100630772; called by muse, mutect2
- TSPAN19 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.862); catalogued as COSV101468076; called by muse, mutect2
- TXNRD1 | c.1610A>G p.E537G (on ENST00000525566 / NM_001093771.3; = p.E439G on NM_003330.4) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61598167; called by muse, mutect2, varscan2
- UBA6 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100451613; called by muse, mutect2, varscan2
- UBTF | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100255838; called by muse, mutect2, varscan2
- URB2 | c.4426C>T p.L1476F | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99270877; called by muse, mutect2, varscan2
- USP31 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99564841; called by muse, mutect2, varscan2
- WDR33 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV100459747; called by muse, mutect2, varscan2
- ZEB2 | c.3272C>A p.A1091E | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV100354648, COSV100355508; called by muse, mutect2, varscan2
- ZNF639 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100418398; called by muse, mutect2, varscan2
- ZZZ3 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100890247; called by muse, mutect2
- AGAP4 | c.1643A>G p.Y548C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SMC4 | c.3391del p.R1131Gfs*11 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- ACTRT2 | c.765G>A p.P255= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs145991951; called by muse, mutect2, varscan2
- C8A | c.234C>A p.I78= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100776467; called by muse, mutect2, varscan2
- CCR3 | c.1038A>T p.T346= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100656386; called by muse, mutect2, varscan2
- CD2AP | c.1131G>A p.Q377= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as COSV100830369; called by mutect2, varscan2
- CUL3 | c.864G>A p.L288= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs777880933, COSV100023963, COSV52364289; called by muse, mutect2, varscan2
- DHRS7 | c.177G>A p.S59= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs774766986, COSV99381538; called by muse, mutect2, varscan2
- HSP90AB1 | c.543G>A p.V181= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100807012; called by muse, mutect2, varscan2
- ING1 | c.609C>T p.R203= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs921737582, COSV100312018; called by muse, mutect2, varscan2
- ITPR2 | c.2578C>T p.L860= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV101189887; called by muse, mutect2, varscan2
- KCNV1 | c.1446G>A p.L482= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99818961; called by muse, mutect2, varscan2
- MFN1 | c.705C>T p.L235= | Silent (SNP) | VAF 13/223 reads (6%) | catalogued as COSV99764299; called by muse, mutect2
- NOL4 | c.1224G>A p.L408= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as rs1257647495, COSV52365510; called by muse, mutect2, varscan2
- NRP2 | c.120C>T p.I40= | Silent (SNP) | VAF 65/461 reads (14%) | catalogued as COSV99783756; called by muse, mutect2, varscan2
- OR10S1 | c.876C>A p.I292= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV101602455, COSV73342701; called by muse, mutect2, varscan2
- OR52K1 | c.723G>A p.G241= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as COSV100297604, COSV56903786; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.342C>T p.H114= (on ENST00000259318 / NM_001136562.3; = p.H345= on NM_007203.5) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs374267815; called by muse, mutect2, varscan2
- PCDHA13 | c.1278C>T p.T426= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as rs782071318, COSV56522229, COSV99169696; called by muse, mutect2, varscan2
- PIK3IP1 | c.645A>T p.R215= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99313956; called by muse, mutect2, varscan2
- RANBP2 | c.5145C>T p.S1715= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs139290272; called by muse, mutect2, varscan2
- RPS23 | c.408C>T p.G136= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99688417; called by muse, mutect2, varscan2
- SI | c.3378G>A p.L1126= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as rs1559992260, COSV100014593, COSV52295727; called by muse, mutect2, varscan2
- SLC39A12 | c.1633C>T p.L545= (on ENST00000377369 / NM_001145195.2; = p.L508= on NM_152725.3) | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV101069915, COSV66203048; called by muse, mutect2, varscan2
- STX12 | c.600G>A p.Q200= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100881278; called by muse, mutect2, varscan2
- TBL2 | c.561C>T p.H187= | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as rs1554588171, COSV99979535; called by muse, mutect2, varscan2
- TFAP2B | c.1131G>A p.P377= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as rs140849621; ClinVar: likely benign; called by muse, mutect2, varscan2
- THADA | c.1320G>A p.L440= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV100368184; called by muse, mutect2, varscan2
- TTN | c.48G>A p.V16= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100601225; called by muse, mutect2, varscan2
- USP53 | c.441A>G p.K147= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99917585; called by muse, mutect2, varscan2
- ZSCAN5A | c.604C>T p.L202= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99569899; called by muse, varscan2
- NXF5 | n.1290G>A | RNA (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99534183; called by muse, mutect2
- PARGP1 | n.934C>T | RNA (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- RGS17 | c.-1A>T | 5'UTR (SNP) | VAF 26/201 reads (13%) | catalogued as COSV99242674; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302088 G>C | 5'Flank (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- ZNF271P | n.1945C>T | RNA (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
